Somatic mutation profile of tumor specimen TCGA-CJ-4634-01A (aliquot TCGA-CJ-4634-01A-02D-1386-10) from TCGA case TCGA-CJ-4634, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 60.7 years (22,155 days).
Specimen TCGA-CJ-4634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58773e67-9a7a-4918-881f-05f2f4658cf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4634-11A (Solid Tissue Normal), aliquot TCGA-CJ-4634-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17057694-16dd-490e-9cf6-ac33f221dadc

The open-access MAF lists 90 somatic variants for this specimen: 66 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 48, Silent 24, Frame Shift Del 6, Nonsense Mutation 5, Frame Shift Ins 3, In Frame Del 2, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs199633532, CM067634, COSV54368245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 170/605 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53203208; called by muse, mutect2, varscan2
- CAMSAP1 | c.3095G>A p.S1032N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as COSV56728250; called by muse, mutect2, varscan2
- CCNG2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs747979305, COSV60353380; called by muse, mutect2, varscan2
- CCNH | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 129/413 reads (31%) | catalogued as COSV56926181; called by muse, mutect2, varscan2
- CD6 | c.1630C>A p.H544N | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV57842535; called by muse, mutect2, varscan2
- CELSR3 | c.7801G>C p.V2601L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51146827; called by muse, mutect2, varscan2
- CMKLR1 | c.433G>A p.V145I (on ENST00000312143 / NM_001142344.2; = p.V143I on NM_004072.3) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as rs936383277, COSV56437970, COSV56441842; called by muse, mutect2, varscan2
- COL13A1 | c.1653A>T p.G551= (on ENST00000398978 / NM_001130103.2; = p.G532= on NM_080800.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 96/354 reads (27%) | catalogued as COSV62574961; called by muse, mutect2, varscan2
- COL13A1 | c.1654G>T p.E552* (on ENST00000398978 / NM_001130103.2; = p.E533* on NM_080800.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 96/354 reads (27%) | catalogued as COSV62574973; called by muse, mutect2, varscan2
- COL15A1 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV66649030; called by muse, mutect2, varscan2
- CUBN | c.1078T>C p.C360R | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64726747; called by muse, mutect2, varscan2
- DCAF5 | c.2428G>A p.G810S | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV58463004; called by muse, mutect2, varscan2
- DGKH | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54941579; called by muse, mutect2, varscan2
- DYNC1H1 | c.12686G>A p.G4229D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV64136430; called by mutect2, varscan2
- ERVFRD-1 | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as COSV65369944; called by muse, mutect2, varscan2
- FMR1NB | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 210/642 reads (33%) | catalogued as COSV63272999; called by muse, mutect2
- FPR3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV59329223; called by muse, mutect2, varscan2
- HIF1A | c.1011T>A p.C337* | Nonsense Mutation (SNP) | VAF 81/277 reads (29%) | catalogued as COSV60191583; called by muse, mutect2, varscan2
- ITIH4 | c.1136T>A p.L379H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56578533; called by muse, mutect2, varscan2
- JSRP1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV55556944; called by muse, mutect2, varscan2
- KLF9 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV65808156; called by muse, mutect2, varscan2
- KRT85 | c.399G>C p.R133S | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV57738202; called by muse, mutect2, varscan2
- L3MBTL4 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV53139672; called by muse, varscan2
- LPCAT4 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 135/381 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV59218938; called by muse, mutect2, varscan2
- LRP1B | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 48/487 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.192); catalogued as COSV67272382; called by muse, mutect2
- LRRC1 | c.1540A>C p.N514H | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as COSV63830770; called by muse, mutect2, varscan2
- MAP1A | c.5992C>T p.P1998S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV100289318; called by muse, mutect2
- NIF3L1 | c.860C>A p.T287N (on ENST00000409020 / NM_001369444.1; = p.T260N on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs368107216; called by muse, mutect2, varscan2
- NPC1L1 | c.2867A>C p.D956A | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56930096; called by muse, mutect2, varscan2
- NRK | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 141/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54606195, COSV99074754; called by muse, mutect2, varscan2
- PBRM1 | c.1583A>T p.N528I | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.635); catalogued as COSV56268961, COSV56271832; called by muse, mutect2, varscan2
- PCARE | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 47/146 reads (32%) | catalogued as rs1439930038, CM1511739, COSV59057907; called by muse, mutect2, varscan2
- PGBD1 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV52555994; called by muse, mutect2, varscan2
- PLEKHM1 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as COSV69599410; called by muse, mutect2, varscan2
- PNO1 | c.723T>G p.I241M | Missense Mutation (SNP) | VAF 172/534 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV52249329; called by muse, mutect2, varscan2
- RIPPLY3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs759464387, COSV61567172; called by muse, mutect2, varscan2
- SIX4 | c.685T>A p.C229S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV53671457; called by muse, mutect2, varscan2
- SLC22A7 | c.788C>T p.A263V (on ENST00000372585 / NM_153320.2; = p.A261V on NM_006672.3) | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs1346693216, COSV65356238; called by muse, mutect2, varscan2
- SLC23A1 | c.1447A>C p.N483H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.828); catalogued as COSV62297597; called by muse, mutect2, varscan2
- STIL | c.3277T>A p.F1093I | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.328); catalogued as COSV54553551; called by muse, mutect2, varscan2
- TDRD9 | c.875G>C p.C292S | Missense Mutation (SNP) | VAF 254/764 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV59155663; called by muse, mutect2, varscan2
- TEX15 | c.4018G>A p.A1340T (on ENST00000256246; = p.A1723T on NM_001350162.2) | Missense Mutation (SNP) | VAF 103/309 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs148542296; called by muse, mutect2, varscan2
- TGFB2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV65109360; called by muse, mutect2, varscan2
- TMC2 | c.2332G>T p.V778F | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62654843; called by muse, mutect2, varscan2
- TRAM1L1 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as COSV60293269; called by muse, varscan2
- TRIP12 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 40/688 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99390680; called by muse, mutect2
- USP37 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 147/544 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51441348; called by muse, mutect2, varscan2
- VHL | c.441_444dup p.A149Ffs*26 | Frame Shift Ins (INS) | VAF 82/236 reads (35%) | catalogued as COSV56544361, COSV56568596; called by pindel, varscan2
- VPS18 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55032160; called by muse, mutect2
- ZNF274 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as COSV58766813; called by muse, mutect2, varscan2
- ZNF521 | c.1240T>G p.L414V | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV64131710; called by muse, mutect2, varscan2
- ZNF532 | c.2465C>T p.S822L | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs771503724, COSV60174014; called by muse, mutect2
- ZNF875 | c.961A>G p.R321G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60993702; called by muse, mutect2, varscan2
- BCL7A | c.279del p.N93Kfs*70 | Frame Shift Del (DEL) | VAF 39/136 reads (29%) | called by mutect2, pindel, varscan2
- BCOR | c.4322_4339del p.Q1441_S1446del (on ENST00000378444 / NM_001123385.2; = p.Q1407_S1412del on NM_017745.6) | In Frame Del (DEL) | VAF 29/130 reads (22%) | called by pindel, varscan2*
- FUT6 | c.821_846del p.G274Vfs*115 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1642A>C p.I548L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); called by muse, varscan2
- KIF4B | c.1643del p.N548Tfs*14 | Frame Shift Del (DEL) | VAF 77/266 reads (29%) | called by mutect2, pindel, varscan2
- LAMB1 | c.2226_2233del p.N742Kfs*17 | Frame Shift Del (DEL) | VAF 36/151 reads (24%) | called by mutect2, pindel, varscan2
- LCN1 | c.214_215del p.T72Hfs*18 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- MAGI1 | c.1557_1559del p.V520del | In Frame Del (DEL) | VAF 38/75 reads (51%) | called by mutect2, pindel, varscan2
- NAT8 | c.289dup p.I97Nfs*8 | Frame Shift Ins (INS) | VAF 36/136 reads (26%) | called by mutect2, pindel, varscan2
- PZP | c.4067_4070dup p.C1358Nfs*32 | Frame Shift Ins (INS) | VAF 64/234 reads (27%) | called by pindel, varscan2
- SACS | c.10511del p.L3504Yfs*22 | Frame Shift Del (DEL) | VAF 21/171 reads (12%) | called by mutect2, pindel, varscan2
- TNRC6A | c.3414_3416dup p.T1139dup | In Frame Ins (INS) | VAF 133/488 reads (27%) | called by mutect2, varscan2
- ABCA8 | c.1213T>C p.L405= | Silent (SNP) | VAF 117/314 reads (37%) | catalogued as COSV52211609; called by muse, mutect2, varscan2
- ADGRE3 | c.1587T>C p.I529= | Silent (SNP) | VAF 26/479 reads (5%) | catalogued as COSV99506467; called by muse, mutect2
- ADORA3 | c.756C>T p.I252= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as COSV53986822; called by muse, mutect2, varscan2
- ARHGEF26 | c.1662G>A p.K554= | Silent (SNP) | VAF 38/798 reads (5%) | catalogued as COSV100726651; called by muse, mutect2
- CCDC42 | c.111G>A p.S37= | Silent (SNP) | VAF 88/427 reads (21%) | catalogued as rs149123321; called by muse, mutect2, varscan2
- CELF5 | c.1452C>A p.P484= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as COSV53013159, COSV53015035; called by muse, mutect2, varscan2
- DYSF | c.5490C>A p.L1830= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as COSV50568662; called by muse, mutect2, varscan2
- FLG | c.9705T>C p.A3235= | Silent (SNP) | VAF 75/245 reads (31%) | catalogued as COSV64248579; called by muse, mutect2, varscan2
- IQGAP2 | c.681A>G p.K227= | Silent (SNP) | VAF 94/280 reads (34%) | catalogued as COSV57181921; called by muse, mutect2, varscan2
- LMNA | c.927C>G p.L309= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV61544024; called by muse, varscan2
- MAMSTR | c.987G>A p.L329= (on ENST00000318083 / NM_001130915.2; = p.L226= on NM_182574.2) | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV58883253; called by muse, mutect2
- MED4 | c.9G>C p.A3= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs776021080, COSV51640486; called by muse, mutect2, varscan2
- NUP214 | c.4101C>G p.G1367= | Silent (SNP) | VAF 71/188 reads (38%) | catalogued as COSV63911410, COSV63913058; called by muse, mutect2, varscan2
- OBSCN | c.17451C>T p.P5817= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs768480879, COSV52826049; called by muse, mutect2, varscan2
- PCDHB6 | c.1338C>T p.A446= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs1486010002, COSV50728097; called by muse, mutect2, varscan2
- PRKCB | c.1362G>C p.L454= | Silent (SNP) | VAF 29/429 reads (7%) | catalogued as COSV57800017; called by muse, mutect2
- RIPK1 | c.438T>C p.V146= | Silent (SNP) | VAF 90/296 reads (30%) | catalogued as rs1417021714, COSV52531643; called by muse, mutect2, varscan2
- ROCK1 | c.2106T>C p.H702= | Silent (SNP) | VAF 46/1142 reads (4%) | catalogued as COSV101296508; called by muse, mutect2
- SETD5 | c.1290A>C p.P430= | Silent (SNP) | VAF 125/225 reads (56%) | catalogued as COSV56717168; called by muse, mutect2, varscan2
- SLC27A6 | c.663C>T p.Y221= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs777493797, COSV52487522; called by muse, mutect2, varscan2
- TRA2A | c.600G>A p.A200= | Silent (SNP) | VAF 337/1005 reads (34%) | catalogued as rs770217015, COSV51718534; called by muse, mutect2, varscan2
- WTAP | c.627C>A p.I209= | Silent (SNP) | VAF 54/100 reads (54%) | catalogued as COSV64329952, COSV64330702; called by muse, mutect2, varscan2
- YEATS2 | c.2106G>C p.V702= | Silent (SNP) | VAF 57/182 reads (31%) | catalogued as rs1023955424, COSV100527441, COSV59372252; called by muse, mutect2, varscan2
- ZNF827 | c.381G>A p.L127= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV65231676; called by muse, mutect2, varscan2
